Gene-level copy-number profile of tumor specimen TCGA-RD-A8MW-01A from TCGA case TCGA-RD-A8MW, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 72.8 years (26,590 days).
Specimen TCGA-RD-A8MW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.aa504884-7bac-441f-82dd-d8bf87720557.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RD-A8MW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/099f5c2a-1c0a-4059-a3f9-3656c70452ac

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,051; copy number 2: 21,367; copy number 3: 26,878; copy number 4: 5,738; copy number 5: 1,215; copy number 6: 1,194; copy number 7: 379; copy number 8: 19; copy number 9: 115; copy number 10: 26; copy number 11: 20; copy number 12: 108; copy number 14: 159; copy number 15: 91; copy number 16: 108; copy number 17: 2; copy number 18: 2; copy number 19: 25; copy number 21: 148; copy number 22: 58; copy number 24: 5; copy number 27: 13; copy number 30: 26; copy number 46: 8; copy number 49: 57.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RD-A8MW-01A-11D-A363-01): tumor purity 0.27, ploidy 2.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,369 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:134,313,576–144,445,844, 172 genes, copy number 16–30 (broad region; genes not listed).
- chr4:47,914,142–49,589,529, 38 genes, copy number 7 (within-gene range 2–7): NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4, AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:70,360,760–76,007,509, 97 genes, copy number 7 (broad region; genes not listed).
- chr4:76,021,118–76,023,497, 1 gene, copy number 7: CXCL10.
- chr6:99,124,609–108,526,796, 114 genes, copy number 11–49 (within-gene range 3–49) (broad region; genes not listed).
- chr7:75,416,786–100,797,797, 440 genes, copy number 7–22 (within-gene range 2–34) (broad region; genes not listed).
- chr11:45,095,806–45,235,292, 2 genes, copy number 16: PRDM11, AC103681.2.
- chr11:57,576,292–57,619,171, 2 genes, copy number 17: RPS4XP13, SERPING1.
- chr11:104,445,868–104,976,116, 7 genes, copy number 10: LINC02552, AP001485.1, AP002004.1, CASP12, CASP4LP, CASP4, AP001153.1.
- chr11:108,308,519–109,823,893, 17 genes, copy number 7: C11orf65, POGLUT3, EXPH5, DDX10, RPS2P39, AP002453.1, CYCSP29, AP003027.1, AP003123.1, RNU6-654P, RNA5SP349, SNORD39, AP003049.2, C11orf87, AP003049.1, AP003102.1, LINC02715.
- chr11:109,907,004–109,985,660, 4 genes, copy number 7: TFAMP2, AP001981.2, RPSAP50, AP001981.1.
- chr11:114,512,706–114,707,069, 7 genes, copy number 9: NXPE2P1, AC020549.3, NXPE1, AC020549.1, NXPE4, AC020549.2, NXPE2.
- chr14:18,333,726–21,830,070, 214 genes, copy number 7 (broad region; genes not listed).
- chr16:10,840,384–10,943,021, 5 genes, copy number 24 (within-gene range 3–24): AC133065.2, AC133065.1, CIITA, DEXI, AC133065.3.
- chr16:11,547,722–11,828,845, 8 genes, copy number 9 (within-gene range 3–9): LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4.
- chr16:12,545,482–12,557,694, 2 genes, copy number 18: AC131391.1, AC010333.1.
- chr20:41,991,140–42,063,969, 3 genes, copy number 14: AL049812.2, AL049812.1, AL049812.3.
- chr20:43,590,937–46,308,498, 113 genes, copy number 9–14 (within-gene range 4–14) (broad region; genes not listed).
- chr20:46,894,624–47,188,844, 1 gene, copy number 14 (within-gene range 5–14): EYA2.
- chr20:46,997,596–48,136,844, 29 genes, copy number 14–27: GAPDHP54, AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1, SULF2, AL354813.1, RNU7-173P, SRMP1, RNA5SP486, RNU7-92P, AL357558.2, AL357558.1, AL357558.3, LINC01522, LINC01523, AL139351.2, AL139351.3, AL139351.1, AL136102.1.
- chr20:49,113,339–53,495,330, 85 genes, copy number 8–14 (within-gene range 4–46) (broad region; genes not listed).
- chr20:53,421,199–53,741,797, 8 genes, copy number 46: PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1.

Autosomal genes at a single copy (total copy number 1): 1,967. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
